Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A2PI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A2PI-01A (Primary Tumor).

[page 1 of 2]
		8/23/11

RUN DATE:
RUN TIP
BY:

PATIENT: ACCT #: LOC: U#:
AGE/SX: RM/BED: REG:
REG DR: STATUS: TLOC: DIS:

SPEC #: PN:: Obtained: Subm Dr:
STATUS: Received:

CLINICAL HISTORY:

CERVICAL CANCER PROCTOSCOPY, CYSTOSCOPY

SPECIMEN/PROCEDURE:

1. CERVIX -
2. CERVIX -
3. BLADDER, NOS
4. CERVIX

ICD-O-3
carcinoma, squamous cell, large cell,
nonkeratinizing 8072/3
Site: Cervix, NOS C53.9
w 8/23/11

IMPRESSION:

- 1) CERVIX, BIOPSY:
Invasive squamous cell carcinoma, large cell nonkeratinizing type; moderately differentiated; see comment.
- 2) CERVIX, BIOPSY:
Invasive squamous cell carcinoma, large cell focally keratinizing type; moderately differentiated; see comment.
- 3) URINARY BLADDER, BIOPSY:
Benign urothelial mucosa with extensive epithelial denudement and focal nonkeratinizing glycogenated squamous epithelium.
Mild chronic cystitis.
- 4) CERVIX, BIOPSY:
Invasive squamous cell carcinoma, large cell nonkeratinizing type; moderately differentiated; see comment.

Dictated
Entered:

COMMENT:

Invasive squamous cell carcinoma involves the full thickness of most of the biopsy pieces (specimens #2 and #4); the depth of invasion cannot be adequately evaluated.

Representative section (specimen #4) reviewed at

** CONTINUED ON NEXT PAGE **

[page 2 of 2]
COMMENT: (continued)

Entered:

GROSS DESCRIPTION:

- 1) Received in formalin labeled with the patient's name and is one pale tan rubbery portion of tissue, 0.6 x 0.4 x 0.2 cm. The specimen is entirely submitted in one cassette.
- 2) Received in formalin labeled with the patient's name and is one pale tan rubbery portion of tissue, 0.6 x 0.5 x 0.4 cm. The specimen is entirely submitted in one cassette.
- 3) Received without fixative, labeled "bladder biopsy" and with the patient's name, is one irregular gray-tan glistening portion of tissue, 0.5 x 0.1 x 0.1 cm. The specimen is entirely submitted in one cassette.
- 4) Received in formalin, labeled "cervical biopsy" and with the patient's name, is one red to red-tan glistening portion of tissue, 0.9 x 0.8 x 0.3 cm. The specimen is trisected and entirely submitted in one cassette.

Dictated by:

Entered:

COPIES TO:

CPT Codes:

BLADDER BIOPSY

CERVICAL BIOPSY

ICD9 Codes:

Resident Physician:

I have personally reviewed the material
(specimen/slide) and approve this final report.

Electronically Signed by: _____

** END OF REPORT **

Source: NCI Genomic Data Commons file 4701a57e-812c-434c-80f6-9b4d3da3cd61 (TCGA-EK-A2PI.1DA80321-4DC2-4BEF-B932-1B38B6BEDB24.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).